Surgical pathology report (de-identified scan), TCGA case TCGA-BB-7871, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-7871-01A (Primary Tumor).

[page 1 of 10]
=====

INTERPRETATION AND DIAGNOSIS: [REDACTED] [REDACTED]

- 1) HYPOGLOSSAL NERVE (BIOPSY): PORTION OF NERVE, NEGATIVE FOR TUMOR.
- 2) RIGHT SOFT TISSUE ON VAGUS (BIOPSY): INFILTRATING SQUAMOUS CELL CARCINOMA.
- 3) RIGHT TONSIL (BIOPSY): SQUAMOUS MUCOSA WITH SALIVARY GLAND TISSUE AND SKELETAL MUSCLE, NEGATIVE FOR TUMOR.
- 4) RIGHT DEEP BASE ON TONGUE (BIOPSY): FIBROADIPOSE TISSUE AND SALIVARY GLAND TISSUE, NEGATIVE FOR TUMOR.
- 5) RIGHT BASE OF TONGUE MUCOSA (BIOPSY): TONSILLAR TISSUE, NEGATIVE FOR TUMOR.
- 6) LEFT BASE OF TONGUE MUCOSA (BIOPSY): INFILTRATING SQUAMOUS CELLS CARCINOMA.
- 7) DEEP BASE OF TONGUE MIDLINE (BIOPSY): FIBROMUSCULAR TISSUE, NEGATIVE FOR TUMOR.
- 8) LEFT BASE OF TONGUE (BIOPSY): SQUAMOUS MUCOSA WITH SALIVARY GLAND TISSUE AND SKELETAL MUSCLE, NEGATIVE FOR TUMOR.
- 9) RIGHT NECK LEVEL 1B (EXCISION): SEROMUCINOUS SALIVARY GLAND, NEGATIVE FOR TUMOR.
- 10) RIGHT NECK (DISSECTION): METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING SEVENTEEN (17) OF FORTY-ONE (41) LYMPH NODES (7/10 IN LEVEL II, 2/6 IN LEVEL III, 8/18 IN LEVEL IV, AND 0/7 IN LEVEL V). LARGEST FOCUS: 4.0 CM (LEVEL II). EXTRANODAL EXTENSION IDENTIFIED.
- 11) LEFT NECK LEVEL 1B (EXCISION): SEROMUCINOUS SALIVARY GLAND, NEGATIVE FOR TUMOR.
- 12) LEFT NECK LEVEL 2B (DISSECTION): METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING EIGHT (8) OF FOURTEEN (14) LYMPH NODES. LARGEST FOCUS: 0.8 CM. EXTRANODAL EXTENSION IS IDENTIFIED.
- 13) LEFT NECK (DISSECTION): METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING NINETEEN (19) OF THIRTY-FIVE (35) LYMPH NODES (4/4 IN LEVEL II, 8/9 IN LEVEL III, 6/13 IN LEVEL IV, 1/9 IN LEVEL V). LARGEST FOCUS: 2.7 CM. EXTRANODAL EXTENSION IDENTIFIED.
- 14) LARYNX AND BASE OF TONGUE (TOTAL LARYNGECTOMY):

SPECIMEN:

Laryngectomy, bilateral neck dissections

[REDACTED]

FINAL DOCUMENT

[REDACTED]

[page 2 of 10]
TUMOR SITE:

Tumor centered in base of tongue with involvement of supraglottis, glottis and subglottis.

HISTOLOGIC TYPE:

Squamous cell carcinoma

TUMOR SIZE:

Greatest dimension: 3.5 cm

HISTOLOGIC GRADE:

G2: Moderately differentiated

LYMPH NODES:

Metastatic carcinoma in 45 of 91 lymph nodes.

Specify largest node: 4.0 cm.

EXTRANODAL EXTENSION:

Present (extensive)

EXTENT OF INVASION

PRIMARY TUMOR:

Tumor of Oropharynx (Base of tongue)

pT4a: Tumor invades larynx. See note.

REGIONAL LYMPH NODES:

pN2: Metastasis in single or multiple lymph nodes, none larger than 6 cm.

MARGINS:

Carcinoma involves base of tongue/superior specimen margin. Other specimen margins uninvolved. (Please see specimens 1-8 and 16 for additional margins)

VENOUS/LYMPHATIC INVASION:

Present, including large vessel invasion

PERINEURAL INVASION:

Present

NOTE: Sections through the thyroid cartilage show no definite tumor invasion.

15) RIGHT SKULL BASE RETROPHARYNGEAL NODE (EXCISION): METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING ONE (1) LYMPH NODE. LARGEST FOCUS: 1.6 CM. EXTRANODAL EXTENSION IS IDENTIFIED.

16) BASE OF TONGUE (EXCISION): INVASIVE SQUAMOUS CELL CARCINOMA. TUMOR EXTENDS TO <1 MM OF THE UNDESIGNATED CAUTERIZED MARGIN.

Electronic signature by which I attest that the above diagnosis is based upon my personal examination of the slides (and / or other material indicated in the diagnosis), and that I have reviewed and approved this report.

Clinical History:

TOTAL LARYNGECTOMY

FINAL DOCUMENT

[page 3 of 10]
GROSS DESCRIPTION

PART #1: FS: HYPOGLOSSAL NERVE [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

FS: Hypoglossal nerve: Nerve margin (designated with clip):

Negative for tumor.

Dictated by: [REDACTED]

The specimen is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'hypoglossal nerve - look at side with staple.' The specimen consists of a red-pink portion of soft tissue measuring 1.5 x 0.7 x 0.3 cm. A staple is present at one end. This area is inked black and submitted for frozen section diagnosis. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS

1 - FSC - 1 (TISSUE FOR FROZEN SECTION)
1 - A - 4 (REMAINDER OF SPECIMEN)
2 - TOTAL - 5

PART #2: FS: RIGHT SOFT TISSUE ON VAGUS [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

FS: Right soft tissue on vagus: Positive for tumor; infiltrating squamous cell carcinoma.

Dictated by: [REDACTED]

The specimen is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'right soft tissue on vagus nerve.' The specimen consists of a 1.4 x 0.2 x 0.2 cm portion of pink-tan soft tissue. The specimen is submitted in its entirety for frozen section diagnosis.

SUMMARY OF SECTIONS

1 - FSC - 1
1 - TOTAL - 1

PART #3: FS: RIGHT TONSIL [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

FINAL DOCUMENT

[page 4 of 10]
FS: Right tonsil: Negative for tumor.

Dictated by: [REDACTED]

The specimen is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'right tonsil.' The specimen consists of a single piece of red-tan soft tissue measuring 0.7 x 0.5 x 0.3 cm. The specimen is submitted in its entirety for frozen section diagnosis.

SUMMARY OF SECTIONS

1 - FSC - 1
1 - TOTAL - 1

PART #4: FS: RIGHT DEEP BASE OF TONGUE [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

FS: Right deep base of tongue: Negative for tumor.

Dictated by: [REDACTED]

The specimen is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'right deep base of tongue.' The specimen consists of a single piece of pink-tan soft tissue measuring 1.0 x 0.4 x 0.3 cm. 100% of the specimen is submitted for frozen section diagnosis.

SUMMARY OF SECTIONS

1 - FSC - 1
1 - TOTAL - 1

PART #5: FS: RIGHT BASE OF TONGUE MUCOSA [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

FS: Right base of tongue mucosa: Negative for tumor.

Dictated by: [REDACTED]

The specimen is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'right base of tongue mucosa.' The specimen consists of a single piece of pink-tan soft tissue measuring 1.5 x 0.5 x 0.5 cm. 100% of the specimen is submitted for frozen section diagnosis.

SUMMARY OF SECTIONS

1 - FSC - 1
1 - TOTAL - 1

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 5 of 10]
PART #6: FS: LEFT BASE OF TONGUE MUCOSA [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists: [REDACTED]

FS: Left base of tongue mucosa: Positive for tumor.

Dictated by: [REDACTED]

The specimen is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'Left base of tongue mucosa.' The specimen consists of a single piece of pink-tan soft tissue measuring 1.7 x 0.5 x 0.2 cm. 100% of the specimen is submitted for frozen section diagnosis.

SUMMARY OF SECTIONS

1 - FSC - 1

1 - TOTAL - 1

PART #7: FS: DEEP BASE OF TONGUE MIDLINE [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists: [REDACTED]

FS: Deep base of tongue midline: Negative for tumor.

Dictated by: [REDACTED]

The specimen is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'Deep base of tongue midline.' The specimen consists of a single piece of pink-tan soft tissue measuring 0.8 x 0.6 x 0.5 cm. 100% of the specimen is submitted for frozen section diagnosis.

SUMMARY OF SECTIONS

1 - FSC - 1

1 - TOTAL - 1

PART #8: FS: LEFT BASE OF TONGUE [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists: [REDACTED]

FS: Left base of tongue: Negative for tumor.

Dictated by [REDACTED]

The specimen is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'Left base of tongue.' The specimen consists of one fragment of pink-tan soft tissue measuring 1.8 x 1.0 x 0.5 cm. The specimen is submitted for frozen

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 6 of 10]
section diagnosis.

SUMMARY OF SECTIONS

1 - FSC - 1 (LEFT BASE OF TONGUE)
1 - TOTAL - 1

PART #9: RIGHT NECK LEVEL 1B [REDACTED]

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received fresh labeled with the patient's name, [REDACTED] and designated 'Right neck level 1B.' The specimen consists of a single piece of brown to yellow fibroadipose tissue measuring 5.0 x 3.0 x 1.0 cm. Grossly, the specimen resembles a submandibular salivary gland with a small amount of fibroadipose tissue attached. The submandibular gland is serially sectioned to reveal unremarkable, lobulated, tan-brown parenchyma with no nodules or other lesions grossly identified. Representative sections of the submandibular gland in addition to all of the attached fibroadipose tissue are submitted. Approximately 30% of the specimen is submitted.

SUMMARY OF SECTIONS

1 - A - 1 (SOFT TISSUE)
1 - B - 2 (SUBMANDIBULAR GLAND)
2 - TOTAL - 3

PART #10: RIGHT RADICAL NECK DISSECTION LEVELS 2-5 [REDACTED]

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received labeled with the patient's name, [REDACTED] and designated 'right radical neck dissection level 2-5.' The specimen consists of a single piece of tan to yellow fibroadipose tissue measuring 15.0 x 5.0 x 3.0 cm. Along the length of the specimen are several sets of staple marks with a number of staples corresponding to the level in the neck. Conjoining the level 2 and level 3 segments is a large ill-defined nodular mass that measures approximately 4.0 x 3.5 x 2.5 cm. Sectioning into this nodule reveals an infiltrating white nodular mass that appears to meld into the surrounding fibroadipose tissue and muscle. Also within the level 2 section, five potential lymph nodes are found ranging in size from 1.5 to 0.5 cm in greatest dimension. The largest lymph node is trisected to reveal a pale tan parenchyma with a white hard nodule within it. Within the level 3 segment aside from the large nodule, five potential lymph nodes are dissected out ranging in size from 1.8 to 0.3 cm in greatest dimension. The largest lymph node is trisected to reveal a dark red and tan mottled parenchyma. Within the level 4 segment, 11 potential lymph nodes are found ranging in size from 2.6 to 0.4 cm in greatest dimension. The largest lymph node is trisected to reveal a variegated tan and yellow hard nodular parenchyma. The second largest lymph node which measures 1.6 cm is also bisected to reveal a variegated surface that is tan and white. Within the level 5 segment, no potential lymph nodes are found. Representative sections of the nodules in levels 2 and 3 are submitted. All potential lymph nodes are submitted. All associated fibroadipose tissue is

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 7 of 10]
submitted. Approximately 80% of the specimen is submitted.

SUMMARY OF SECTIONS

1 - A - 3 (1 LN TRISECTED LEVEL 2)
1 - B - 3 (3 LNS LEVEL 2)
4 - C-F - 1 EACH (NODULE LEVEL 2-3)
2 - G-H - 1 EACH (SOFT TISSUE, LEVEL 2)
1 - I - 3 (1 LN TRISECTED, LEVEL 3)
1 - J - 4 (4 LNS LEVEL 3)
1 - K - 1 (SOFT TISSUE, LEVEL 3)
1 - L - 1 (1 LN, LEVEL 4)
1 - M - 2 (2ND HALF OF LN IN L)
1 - N - 2 (1 LN, BISECTED)
1 - O - 4 (4 LNS, LEVEL 4)
1 - P - 5 (5 LNS, LEVEL 4)
4 - Q-T - MULTIPLE EACH (SOFT TISSUE LEVEL 4)
5 - U-Y - MULTIPLE EACH (SOFT TISSUE LEVEL 5)
25 - TOTAL - M

SUMMARY OF SECTIONS

1 - FSC - 1
1 - TOTAL - 1

PART #11: LEFT NECK LEVEL 1B

Resident Pathologist:

Dictated by:

The specimen is received fresh labeled with the patient's name, and designated 'left neck level 1B.' The specimen consists of one roughly ovoid shaped portion of dark yellow soft tissue consistent with submandibular gland weighing 8.9 gm and measuring 4.6 x 3.0 x 1.0 cm. No orientation is provided. The specimen is inked black and serially sectioned to reveal dark yellow, lobulated, unremarkable parenchyma. Representative sections are submitted.

SUMMARY OF SECTIONS

3 - A-C - 1 EACH (SUBMANDIBULAR GLAND)
3 - TOTAL - 3

PART #12: LEFT NECK LEVEL 2B

Resident Pathologist:

Dictated by:

The specimen is received fresh labeled with the patient's name, and designated 'left neck level 2B.' The specimen consists of a single piece of fibroadipose tissue which measures 5.5 x 2.5 x 1.0 cm. Dissection of the soft tissue reveals eight potential lymph nodes ranging in size from 1.3 to 0.5 cm in greatest dimension. The largest lymph node is bisected to reveal a mottled tan and white nodular mass. All lymph nodes and the remaining fibroadipose tissue are entirely submitted.

SUMMARY OF SECTIONS

FINAL DOCUMENT

[page 8 of 10]
1 - A - 2 (1 LN BISECTED)
1 - B - 3 (3 LNS)
1 - C - 4 (4 LNS)
2 - D,E - MULT EA (FAT)
5 - TOTAL - M

PART #13: LEFT MODIFIED RADICAL NECK DISSECTION LEVELS 2-5

Resident Pathologist:

Dictated by:

The specimen is received fresh labeled with the patient's name, and designated 'left radical neck levels 2-5.' The specimen consists of one large, irregular portion of red-tan to yellow-tan soft tissue measuring 10.0 x 7.5 x 2.0 cm. Two staples are identified designating level 2. Three staples are identified designating level 3. Four staples are identified designating level 4, and five staples are identified designating level 5. Level 2 contains four possible lymph nodes ranging from 0.8 to 2.6 cm in greatest dimension. The largest lymph node displays a tan-white, firm and gritty cut surface. A segment of vessel is also identified measuring 1.0 cm in length by 0.4 cm in average diameter. The remainder of level 2 consists of unremarkable skeletal muscle and fibroadipose tissue. The lymph nodes are entirely submitted. Level 3 contains nine possible lymph nodes ranging from 0.7 to 1.8 cm in greatest dimension. The remainder of level 3 consists of unremarkable fibroadipose tissue and skeletal muscle. The lymph nodes are entirely submitted. Level 4 contains thirteen possible lymph nodes ranging from 0.4 to 1.6 cm in greatest dimension. The remainder of level 4 consists of unremarkable fibroadipose tissue. The lymph nodes are entirely submitted. Level 5 contains ten possible lymph nodes ranging from 0.2 to 1.0 cm in greatest dimension. The remainder of level 5 consists of unremarkable fibroadipose tissue and skeletal muscle. The lymph nodes are entirely submitted.

SUMMARY OF SECTIONS

1 - A - 1 (REP. CROSS SECTION OF VESSEL IN LEVEL 2)
1 - B - 2 (2 POSS. LNS LEVEL 2)
1 - C - 2 (1 BISECTED LN, LEVEL 2)
1 - D - 1 (CROSS SECTION OF LARGEST LN, LEVEL 2)
1 - E - 3 (3 POSS. LNS, LEVEL 3)
6 - F-K - 2 EACH (1 BISECTED LN EACH, LEVEL 3)
2 - L-M - 4 EACH (4 POSS. LNS EACH, LEVEL 4)
1 - N - 2 (2 POSS. LNS, LEVEL 4)
3 - O-Q - 2 EACH (1 BISECTED LN EACH LEVEL 4)
2 - R,S - 4 EACH (4 POSS. LNS EACH LEVEL 5)
1 - T - 2 (2 POSS. LNS LEVEL 5)
20 - TOTAL - M

PART #14: TOTAL LARYNGECTOMY PHARYNGECTOMY BASE OF TONGUE

Resident Pathologist:

Dictated by:

The specimen is received fresh labeled with the patient's name, and designated 'total laryngectomy and base of tongue.' The specimen consists of a laryngectomy specimen that includes the base

FINAL DOCUMENT

[page 9 of 10]
of the tongue which measures 8.0 x 7.5 x 5.5 cm. The larynx itself measures 4.5 x 4.5 x 4.0 cm and the distal tracheal margin is 1.7 x 1.8 cm. The specimen is inked black on the outside and is opened along the posterior aspect of the larynx to reveal a large ulcerating mass at the superior aspect of the larynx and at the posterior aspect at the base of the tongue which measures 3.5 x 3.5 cm. This ulceration appear to have eroded away the epiglottis and has grossly involved the false vocal cords, but does not grossly appear to involve the true vocal cords. This ulceration also appears to encroach upon the base of the tongue. The ulceration is 1.0 cm from the proximal base of the tongue margin and is 3.1 cm from the distal tracheal margin. The mass also appears to approach within 1.0 mm of the anterior inked margin at the superior aspect of the specimen near the base of the tongue. The mass does not appear to invade into the thyroid cartilage. Representative sections are submitted as indicated on the photograph.

SUMMARY OF SECTIONS

1 - A - 1	(DISTAL TRACHEAL MARGIN/DECAL)
1 - B - 1	(LEFT BASE OF TONGUE MARGIN)
1 - C - 1	(SUPERIOR BASE OF TONGUE MARGIN)
1 - D - 1	(RIGHT SUPERIOR BASE OF TONGUE MARGIN)
1 - E - 1	(LEFT VOCAL CORDS)
1 - F - 1	(ANTERIOR COMMISSURE)
1 - G - 1	(RIGHT VOCAL CORDS)
1 - H - 1	(LEFT ARYEPIGLOTTIC FOLD AND PYRIFORM SINUS)
1 - I - 1	(RIGHT ARYEPIGLOTTIC FOLD AND PYRIFORM SINUS)
2 - J,K - 1 EACH	(ANTERIOR/SUPERIOR SOFT TISSUE MARGIN)
1 - L - 1	(RIGHT VOCAL CORDS AND THYROID CARTILAGE)
1 - M - 1	(LEFT VOCAL CORDS AND THYROID CARTILAGE)
2 - N,O - 1 EACH	(TUMOR)
15 - TOTAL - 15	

PART #15: RIGHT SKULL BASE RETROPHARYNGEAL NODE [REDACTED]
Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received fresh labeled with the patient's name, [REDACTED] and designated 'right skull base retroperitoneal node.' The specimen consists of a single piece of tan and yellow soft tissue which measures 2.0 x 1.6 x 0.8 cm. The specimen appears to be a nodular lymph node. The specimen is bisected to reveal mottled tan and white interior which grossly appears to be involved by metastatic tumor. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS

1 - A - 2
1 - TOTAL - 2

PART #16: RE RESECTION BASE OF TONGUE [REDACTED]
Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received fresh labeled with the patient's name, [REDACTED] and designated 'Left re-excision base of tongue.' The [REDACTED]

FINAL DOCUMENT

[page 10 of 10]
specimen consists of a single piece of tan and brown soft tissue which measures 3.4 x 1.1 x 0.7 cm. The specimen appears to have a brown, rough surface which appears to be a cut surgical margin and a tan-brown, smooth mucosal margin. The specimen is received unoriented and the entire surgical margin is inked black. The specimen is serially sectioned to reveal unremarkable tan-pink, homogeneous parenchyma. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS

2 - A,B - 5 EACH
2 - TOTAL - 10

Other Surgical Pathology Specimens known to the computer:

=====

(End of Report)

Note: This note provides information pertaining only to a specific event. A more detailed medical history is available in the Medical Record.

FINAL DOCUMENT

Source: NCI Genomic Data Commons file a9a64d81-16e2-42cd-ab59-7e4d70d18836 (TCGA-BB-7871.7D9781C8-90C7-4229-B32D-F7CB232DB91D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).